Somatic mutation profile of tumor specimen C3L-01953-01 (aliquot CPT0389860006) from CPTAC case C3L-01953, project CPTAC-3 (Kidney — Lipomatous Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Angiomyolipoma; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: GX; Age at diagnosis: 72.1 years (26,323 days).
Specimen C3L-01953-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8fb07483-e191-44db-b3fe-af4ea5472e1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01953-31 (Blood Derived Normal), aliquot CPT0389890002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/30cd4e1f-b024-4ad9-af77-470db65689db

The open-access MAF lists 15 somatic variants for this specimen: 10 protein-altering or splice-affecting, 2 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 2, Nonsense Mutation 2, 3'Flank 1, Frame Shift Ins 1, 3'UTR 1, Splice Site 1, Frame Shift Del 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NCOR2 | c.592C>T p.Q198* | Nonsense Mutation (SNP) | VAF 10/286 reads (3%) | catalogued as COSV62299294; called by muse, mutect2
- NCOR2 | c.592-1G>T p.X198_splice | Splice Site (SNP) | VAF 10/290 reads (3%) | catalogued as COSV100657878; called by muse, mutect2
- POLM | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 40/132 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.365); catalogued as rs1054073912; called by muse, mutect2, varscan2
- PRRX1 | c.635A>G p.N212S | Missense Mutation (SNP) | VAF 50/462 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs775185451; called by muse, mutect2, varscan2
- TSC2 | c.1224del p.F408Lfs*17 | Frame Shift Del (DEL) | VAF 114/414 reads (28%) | catalogued as COSV54777381; called by mutect2, pindel, varscan2
- ANK2 | c.1692dup p.T565Yfs*43 | Frame Shift Ins (INS) | VAF 44/416 reads (11%) | called by mutect2, pindel, varscan2
- NKD1 | c.1168C>T p.L390F | Missense Mutation (SNP) | VAF 6/135 reads (4%) | SIFT tolerated (0.6); PolyPhen benign (0.105); called by muse, mutect2
- TP53BP1 | c.1490C>G p.P497R | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TSC2 | c.3919G>T p.E1307* | Nonsense Mutation (SNP) | VAF 54/213 reads (25%) | called by muse, mutect2, varscan2
- USP34 | c.3638T>A p.V1213D | Missense Mutation (SNP) | VAF 8/182 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.086); called by muse, mutect2
- KRT84 | c.1620C>T p.A540= | Silent (SNP) | VAF 12/191 reads (6%) | called by muse, mutect2
- PRKCQ | c.1578C>T p.C526= | Silent (SNP) | VAF 21/240 reads (9%) | called by muse, mutect2
- ESPN | chr1:6461181 T>G | 3'Flank (SNP) | VAF 12/240 reads (5%) | called by muse, mutect2
- FOXP2 | c.*1826G>A | 3'UTR (SNP) | VAF 7/86 reads (8%) | catalogued as rs771404418; ClinVar: uncertain significance; called by muse, mutect2
- ZBP1 | c.1094-2472T>G | Intron (SNP) | VAF 17/176 reads (10%) | called by muse, mutect2
